Gene-level copy-number profile of tumor specimen MP2PRT-PARXIG-TMP1-A from MP2PRT case MP2PRT-PARXIG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Precursor cell lymphoblastic leukemia, NOS; Tissue or organ of origin: Blood; Age at diagnosis: 6.9 years (2,533 days).
Specimen MP2PRT-PARXIG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c4175ec3-7811-4334-8f51-67241ea55e9d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PARXIG-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,732 have no estimate.
https://portal.gdc.cancer.gov/files/10e8bf1a-7ff5-43c6-85d9-d6eaa109624d

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 215; copy number 1: 8; copy number 2: 4,168; copy number 3: 336; copy number 4: 53,476; copy number 5: 75; copy number 6: 36; copy number 7: 350; copy number 8: 227.

Homozygous deletions (total copy number 0; autosomes only): 215 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,857,161–89,245,596, 38 genes (within-gene range 0–4): IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30.
- chr2:90,121,786–90,173,414, 4 genes (within-gene range 0–2): IGKV2D-14, IGKV1D-13, IGKV1D-12, IGKV3D-11.
- chr3:108,043,091–108,091,862, 1 gene: CD47.
- chr7:142,656,701–142,802,748, 32 genes: TRBV24-1, MTRNR2L6, TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1, TRBJ1-1, TRBJ1-2, TRBJ1-3, TRBJ1-4, TRBJ1-5, TRBJ1-6, TRBC1, TRBJ2-1, TRBJ2-2, TRBJ2-2P, TRBJ2-3, TRBJ2-4, TRBJ2-5, TRBJ2-6, TRBJ2-7, TRBC2.
- chr11:36,575,574–36,598,279, 1 gene (within-gene range 0–4): RAG2.
- chr14:22,438,547–22,439,015, 2 genes (within-gene range 0–8): TRDD1, TRDD2.
- chr14:105,672,308–106,481,706, 126 genes (within-gene range 0–2) (broad region; genes not listed).
- chr14:106,531,141–106,538,344, 2 genes (within-gene range 0–1): IGHVIII-47-1, IGHV3-48.
- chr14:106,564,375–106,579,236, 3 genes (within-gene range 0–2): IGHVII-49-1, IGHV3-50, IGHV5-51.
- chr14:106,584,718–106,586,826, 2 genes (within-gene range 0–2): IGHVII-51-2, IGHV3-52.
- chr14:106,723,574–106,775,618, 4 genes: IGHV2-70D, IGHV1-69D, IGHV2-70, IGHV3-71.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 8. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
